Gene-level copy-number profile of tumor specimen TCGA-RW-A686-06A from TCGA case TCGA-RW-A686, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-RW-A686-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.e4d14aab-0998-478e-ad79-b88dff2d81cf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RW-A686-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb976420-d2dd-48ab-a9dc-428f167d279d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,361; copy number 1: 3,692; copy number 2: 53,923; copy number 3: 254; copy number 4: 1; copy number 5: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RW-A686-06A-11D-A35C-01): tumor purity 0.65, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr3:1,595,777–1,596,245, 1 gene: RPL23AP38.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr14:23,969,874–24,051,377, 3 genes (within-gene range 0–2): DHRS4L2, AL136419.1, AL136419.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes, copy number 5: CFHR3, CFHR1.

Autosomal genes at a single copy (total copy number 1): 3,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
